Gene-level copy-number profile of tumor specimen TCGA-YD-A89C-06A from TCGA case TCGA-YD-A89C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.8 years (16,006 days).
Specimen TCGA-YD-A89C-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.558a0c0a-9b56-414f-8861-54ec48d62e36.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YD-A89C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0dc66db8-2db2-4187-8770-e28eacc45522

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,088; copy number 2: 45,244; copy number 3: 11,441; copy number 4: 723; copy number 5: 225; copy number 6: 156; copy number 7: 418; copy number 8: 112; copy number 9: 71; copy number 10: 117; copy number 11: 78; copy number 12: 36; copy number 13: 15; copy number 14: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YD-A89C-06A-11D-A371-01): tumor purity 0.78, ploidy 2.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,317 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,937,812–151,267,479, 66 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:172,532,349–173,363,733, 14 genes, copy number 5 (within-gene range 3–5): SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1, TNFSF4, AL645568.2, AL645568.1.
- chr1:205,712,822–205,783,623, 4 genes, copy number 5: NUCKS1, SNORA72, RAB29, AC119673.1.
- chr1:215,376,484–216,423,448, 6 genes, copy number 5 (within-gene range 1–5): VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1.
- chr1:223,947,605–224,881,355, 28 genes, copy number 5: CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813, AL391811.1.
- chr1:228,100,726–228,378,876, 14 genes, copy number 5 (within-gene range 1–5): C1orf35, MRPL55, FAM96AP2, AL136379.1, AL359510.2, AL359510.1, GUK1, GJC2, IBA57-DT, IBA57, OBSCN-AS1, OBSCN, AL353593.1, AL353593.2.
- chr6:167,607–1,613,897, 32 genes, copy number 6–11: AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr6:2,227,803–5,829,192, 89 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:5,918,564–5,918,844, 1 gene, copy number 5: RN7SL221P.
- chr6:6,534,697–12,008,856, 102 genes, copy number 6–11 (broad region; genes not listed).
- chr6:12,514,110–15,522,300, 41 genes, copy number 7–9: RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P, 5S_rRNA.
- chr6:17,393,505–17,987,635, 12 genes, copy number 7 (within-gene range 4–7): CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1.
- chr6:18,387,350–18,674,001, 3 genes, copy number 9 (within-gene range 4–9): RNF144B, MIR548A1HG, MIR548A1.
- chr6:20,042,455–22,654,455, 31 genes, copy number 5–7 (within-gene range 2–7): AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1.
- chr6:38,168,451–38,715,217, 7 genes, copy number 5: BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1.
- chr6:38,744,086–38,822,404, 3 genes, copy number 5: RN7SL465P, AL035555.2, AL035555.1.
- chr15:61,181,249–61,635,449, 5 genes, copy number 6 (within-gene range 4–6): AC012404.1, AC012404.2, AC107905.1, AC104574.2, AC104574.1.
- chr15:66,498,015–66,524,532, 1 gene, copy number 6 (within-gene range 2–6): RPL4.
- chr15:66,504,959–66,685,794, 3 genes, copy number 6 (within-gene range 2–6): ZWILCH, LCTL, LINC01169.
- chr15:67,832,725–67,873,866, 1 gene, copy number 7 (within-gene range 2–7): AC009292.2.
- chr15:67,974,391–69,099,987, 25 genes, copy number 7–11: AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B, ITGA11, AC100825.1, CORO2B, CARS1P1, ANP32A, MIR4312, SPESP1, AC087639.1, AC087639.2, AC027088.1, NOX5, AC027088.5, AC027088.4, AC027088.3, EWSAT1, AC027088.2.
- chr15:69,462,921–69,843,120, 1 gene, copy number 8 (within-gene range 2–8): DRAIC.
- chr15:69,803,316–70,098,176, 3 genes, copy number 8 (within-gene range 2–8): GEMIN8P1, AC021818.1, TLE3.
- chr15:70,853,239–71,053,658, 1 gene, copy number 7 (within-gene range 2–7): LRRC49.
- chr15:71,063,101–101,933,350, 824 genes, copy number 5–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,088. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
